Surgical pathology report (de-identified scan), TCGA case TCGA-GS-A9TY, project TCGA-DLBC (Lymphoid Neoplasm Diffuse Large B-cell Lymphoma), tissue source site Fundacio Clinic per a la Recerca Biomedica, specimen TCGA-GS-A9TY-01A (Primary Tumor).

AXILLAR LYMPH NODE:

Tissue fragment of 7x5,3x4,3 cm. We identify a lymph node of 4x4,3,4 cm, that presents a pinky color with a whitish area that measures 3,8x3,3 cm. Other three lymph nodes of pinky color are observed, that measure 2,5x2,3x2,2 cm.

LEFT AXILLAR LYMPH NODE, EXCISION:

- DIFFUSE LARGE B-CELL Lymphoma WITH HIGH PROLIFERATIVE INDEX AND POSITIVITY FOR p53.

The specimen corresponds to several lymph ganglions. One of them contains a diffuse large cell lymphoma which is positive for CD20, BCL6 and p53, and negative for BCL2, CD10 and MUM1. CD3 and CD5 show the presence of a scarce presence of intratumoral reactive T-cells. The KI67 proliferative index is 70%.

The associated lymph nodes show a reactive follicular hyperplasia.

No rearrangement of the BCL2 gene by PCR (MBR) has been observed.

IOD-03
Lymphoma, diffuse large B-cell NOS
968013
Site Lymph node, axilla
C773
Sp 01/31/14

Source: NCI Genomic Data Commons file 557d8978-0e3e-4f31-bbde-896fb2e071b7 (TCGA-GS-A9TY.E7D2AFFA-14B9-436F-B76F-C1F5B88D7600.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).